TCGA case TCGA-UW-A72P — Kidney Chromophobe (TCGA-KICH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: University of North Carolina. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1860ba2a-76a9-4ec3-a19f-a05f3f28505a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Renal cell carcinoma, chromophobe type: ICD-O-3 morphology code: 8317/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 61.0 years (22,295 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 769 days (2.1 years).
   Pathology details: Consistent pathology review: Yes; Sarcomatoid present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 376 days (1.0 years); Disease response: Tumor Free.
- Days to follow up: 769 days (2.1 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Lactate Dehydrogenase: Normal.
- Calcium: Elevated.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-UW-A72P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 510 mg.
  Slide TCGA-UW-A72P-01A-02-TS2: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-UW-A72P-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-UW-A72P-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Sarcomatoid features: No; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Lymph nodes examined: No; Tumor status: Tumor free; Tobacco smoking history indicator: 1; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 769 days; disease-specific survival: no event (censored), 769 days; disease-free interval: no event (censored), 769 days; progression-free interval: no event (censored), 769 days.
